TCGA case TCGA-S9-A7J1 — Brain Lower Grade Glioma (TCGA-LGG)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Dept of Neurosurgery at University of Heidelberg. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/33bedfb7-33fb-479d-b997-50c3284c0ac9

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Germany; Age at index: 43 years; Vital status: Alive.

Diagnoses (1)
1. Oligodendroglioma, NOS: ICD-O-3 morphology code: 9450/3; ICD-10 code: C71.0; Tissue or organ of origin: Cerebrum; Site of resection or biopsy: Nervous system, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 43.6 years (15,926 days); Year of diagnosis: 2013; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 249 days; First symptom longest duration: 31-90 Days; First symptom prior to diagnosis: Seizures; Sites of involvement: Brain, Temporal lobe; Supratentorial localization: Cerebral Cortex.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Antiseizure Treatment; Timepoint category: Preoperative.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; Radiation Therapy, NOS to Head, Face or Neck, NOS, prior to diagnosis; adjuvant Radiation Therapy, NOS; Steroid Therapy, preoperative.

Follow-up (2 entries)
- Day -17 (preoperative): Karnofsky performance status: 60; ECOG performance status: 3.
- Days to follow up: 249 days; Disease response: With Tumor.

Molecular and laboratory tests
- IDH1 mutation, nos (IHC): Positive.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Seizure.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-S9-A7J1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 250 mg.
  Slide TCGA-S9-A7J1-01A-02-TS2: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 80; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 30; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-S9-A7J1-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-S9-A7J1-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Central nervous system; Histologic diagnosis: Oligodendroglioma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; History ionizing radiation to head: No; Tumor status: With tumor; Tumor site: Supratentorial, Temporal Lobe; History seizures: Yes; History headaches: No; Symp changes mental status: No; Symp changes visual: No; Symp changes sensory: No; Symp changes motor movement: No; First symptom longest duration: 31 - 90 Days; History asthma: No; History eczema: No; Histor hay fever: No; History dust mold allergy: No; Allergy food diagnosis indicator: No; Allergy animals insects diagnosis indicator: No; History neoadjuvant steroid treatment: No; History neoadjuvant medication: Yes; Idh1 mutation test indicator: Yes; Idh1 mutation found: Yes; Treatment outcome first course: Partial Remission/Response; New tumor event diagnosis indicator: No.
- Follow-up form 1: Lost to follow-up: No; Treatment outcome first course: Partial Remission/Response; Tumor status: With tumor.
- Follow-up form 3: Lost to follow-up: Yes; Treatment outcome first course: Partial Remission/Response; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 249 days; disease-specific survival: no event (censored), 249 days; progression-free interval: no event (censored), 249 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-S9-A7J1-01A-21D-A34I-01): tumor purity 0.76, ploidy 1.94, whole-genome doublings 0.
